Somatic mutation profile of tumor specimen ALCH-B53M-TTP1-A (aliquot ALCH-B53M-TTP1-A-1-0-D-A83F-36) from ALCHEMIST case ALCH-B53M, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.5 years (25,740 days).
Specimen ALCH-B53M-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72cc1c9a-d6fe-4486-b163-d30cabb83029.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B53M-NB2-A (Blood Derived Normal), aliquot ALCH-B53M-NB2-A-1-0-D-A83F-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f24b17e9-63c8-4487-9c97-ec1f02d721b7

The open-access MAF lists 22 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, 3'UTR 3, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 29/574 reads (5%) | hotspot (GDC flag); catalogued as COSV52666332, COSV52700326, COSV52746468; called by muse, mutect2
- CUL7 | c.4145A>G p.Y1382C | Missense Mutation (SNP) | VAF 22/461 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs768491741; called by muse, mutect2
- EIF2B5 | c.2116C>T p.R706C (on ENST00000647909; = p.R698C on NM_003907.3) | Missense Mutation (SNP) | VAF 34/772 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as rs374599117, COSV56606256; called by muse, mutect2
- GRIN2A | c.3976G>A p.G1326S | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.411); catalogued as rs1268143219, COSV58040188; called by muse, mutect2
- HMGXB4 | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs1303845699; called by muse, mutect2
- KIF13A | c.2332G>A p.D778N | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as rs1323522887; called by muse, mutect2
- LRRC37B | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 27/367 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.32); catalogued as rs1167806820; called by muse, mutect2
- MRGPRD | c.74C>T p.T25M | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.333); catalogued as rs771351241; called by muse, mutect2, varscan2
- WT1 | c.532G>A p.G178R | Missense Mutation (SNP) | VAF 30/394 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.46); catalogued as COSV100188103, COSV60073505; called by muse, mutect2
- CEP192 | c.1220A>G p.D407G | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); called by muse, mutect2
- DNAJA1 | c.827C>A p.P276Q | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.808); called by muse, mutect2
- OR2W1 | c.102C>A p.F34L | Missense Mutation (SNP) | VAF 14/418 reads (3%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.993); called by muse, mutect2
- PDGFD | c.560C>A p.T187K | Missense Mutation (SNP) | VAF 40/500 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- RHBDF1 | c.2257G>A p.A753T | Missense Mutation (SNP) | VAF 11/304 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.099); called by muse, mutect2
- ADGRB3 | c.3762A>C p.T1254= | Silent (SNP) | VAF 14/238 reads (6%) | called by muse, mutect2
- CRIM1 | c.807C>T p.P269= | Silent (SNP) | VAF 24/532 reads (5%) | catalogued as rs140450317; called by muse, mutect2
- GMCL2 | c.192G>A p.P64= | Silent (SNP) | VAF 9/159 reads (6%) | called by muse, mutect2
- PLXNA4 | c.3057G>A p.V1019= | Silent (SNP) | VAF 14/227 reads (6%) | called by muse, mutect2
- CTTN | c.*358C>G | 3'UTR (SNP) | VAF 15/298 reads (5%) | called by muse, mutect2
- RSPO1 | c.-9C>T | 5'UTR (SNP) | VAF 32/468 reads (7%) | catalogued as rs530280205, COSV62975147; called by muse, mutect2
- TMEM70 | c.*1075C>G | 3'UTR (SNP) | VAF 12/261 reads (5%) | called by muse, mutect2
- ZNF778 | c.*5068A>G | 3'UTR (SNP) | VAF 22/416 reads (5%) | catalogued as rs1475941295; called by muse, mutect2
